Somatic mutation profile of tumor specimen MP2PRT-PASVAJ-TMP1-A (aliquot MP2PRT-PASVAJ-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASVAJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,256 days).
Specimen MP2PRT-PASVAJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f80b904-85a8-4edf-a967-c78ea6809972.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASVAJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASVAJ-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7285eea-78e0-4584-8e4d-761f611971cd

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5, In Frame Ins 2, Splice Site 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRD7 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 159/393 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1229533673; called by muse, mutect2, varscan2
- FBXO5 | c.818+1G>A p.X273_splice | Splice Site (SNP) | VAF 24/294 reads (8%) | catalogued as COSV57671764; called by muse, mutect2
- MALRD1 | c.3674G>A p.R1225H | Missense Mutation (SNP) | VAF 44/288 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs778174694, COSV101038631; called by muse, mutect2, varscan2
- NID1 | c.3164G>A p.R1055H | Missense Mutation (SNP) | VAF 61/471 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747099610, COSV51618521; called by muse, mutect2, varscan2
- PAPLN | c.2191G>A p.V731M (on ENST00000554301; = p.V704M on NM_173462.4) | Missense Mutation (SNP) | VAF 33/654 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs758226571; called by muse, mutect2
- TEKT3 | c.878+1G>T p.X293_splice | Splice Site (SNP) | VAF 55/328 reads (17%) | catalogued as COSV58627707; called by muse, mutect2, varscan2
- TIGD1 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 35/542 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.553); catalogued as rs958511319; called by muse, mutect2
- CLEC3B | c.412A>G p.M138V | Missense Mutation (SNP) | VAF 270/681 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714682 TCTCTCGCA>GAAG | Missense Mutation (DEL) | VAF 31/88 reads (35%) | called by pindel, varscan2*
- IGHV3-53 | c.350delinsGCC | In Frame Ins (INS) | VAF 9/45 reads (20%) | called by pindel, varscan2*
- IGHV4-59 | c.347_348insGAGGGGAGACCCAAGA p.*117Rfs*? | Frame Shift Ins (INS) | VAF 25/93 reads (27%) | called by pindel, varscan2
- MDH1B | c.137A>T p.D46V | Missense Mutation (SNP) | VAF 25/311 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2
- MYO6 | c.1382A>G p.E461G | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SETD1B | c.3877G>A p.A1293T | Missense Mutation (SNP) | VAF 61/544 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SRGAP1 | c.1497dup p.N500* | Frame Shift Ins (INS) | VAF 94/540 reads (17%) | called by mutect2, pindel, varscan2
- WFS1 | c.413_414insCCCGCTGAA p.R138_R139insPLN | In Frame Ins (INS) | VAF 43/512 reads (8%) | called by mutect2, pindel
- GAS2L3 | c.105C>T p.Y35= | Silent (SNP) | VAF 87/503 reads (17%) | catalogued as rs776903194, COSV57159031; called by muse, mutect2, varscan2
- IGKV4-1 | c.363T>C p.P121= | Silent (SNP) | VAF 68/100 reads (68%) | catalogued as rs569380694; called by muse, varscan2
- IL1R2 | c.765A>T p.T255= | Silent (SNP) | VAF 36/384 reads (9%) | catalogued as rs150067707; called by muse, mutect2
- UNC13C | c.3738A>T p.T1246= | Silent (SNP) | VAF 113/363 reads (31%) | called by muse, mutect2, varscan2
- VPS53 | c.1329G>A p.L443= (on ENST00000571805 / NM_001366253.2; = p.L414= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/296 reads (13%) | catalogued as rs760049033; called by muse, mutect2, varscan2
